Somatic mutation profile of tumor specimen HCM-CSHL-0383-C18-01A (aliquot HCM-CSHL-0383-C18-01A-11D-A78T-36) from HCMI case HCM-CSHL-0383-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 51.4 years (18,766 days).
Specimen HCM-CSHL-0383-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05a0527e-69a2-4523-945a-e00cb642f6cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0383-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0383-C18-10A-01D-A78U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2afa295d-919d-415a-9a55-486337c10ffa

The open-access MAF lists 165 somatic variants for this specimen: 90 protein-altering or splice-affecting, 48 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 48, Intron 11, RNA 7, Splice Site 4, 5'UTR 4, Frame Shift Del 4, Splice Region 2, 3'UTR 2, Nonsense Mutation 2, 3'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.1639C>T p.R547W (on ENST00000359125 / NM_172107.4; = p.R519W on NM_004518.6) | Missense Mutation (SNP) | VAF 108/370 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs796052650, CM131778, COSV60557310; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 140/301 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.379T>A p.S127T | Missense Mutation (SNP) | VAF 112/194 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52667433, COSV52678360, COSV52751962; called by muse, mutect2, varscan2
- A3GALT2 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 113/237 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV57760969; called by muse, mutect2, varscan2
- ANO2 | c.121G>T p.A41S (on ENST00000356134 / NM_001278597.3; = p.A45S on NM_001278596.3) | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs760891155; called by muse, mutect2, varscan2
- C4BPB | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs564412483; called by muse, mutect2, varscan2
- CABIN1 | c.5008-1G>A p.X1670_splice | Splice Site (SNP) | VAF 138/315 reads (44%) | catalogued as COSV99573796; called by muse, mutect2, varscan2
- CCDC170 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs1159721192, COSV53339314, COSV53340316; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as rs747064410; called by mutect2, varscan2
- CHMP1A | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs986506515; called by muse, mutect2, varscan2
- CHTF18 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.11); catalogued as rs373526401; called by muse, mutect2, varscan2
- CLOCK | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 227/403 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs371941858; called by muse, mutect2, varscan2
- CRYGA | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 83/421 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as rs1012021158; called by muse, mutect2, varscan2
- DAGLB | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 39/618 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99766223; called by muse, mutect2
- DCC | c.3742G>A p.V1248M | Missense Mutation (SNP) | VAF 179/288 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs201242417, COSV101473359, COSV71429727; called by muse, mutect2, varscan2
- DOCK5 | c.469A>G p.R157G | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs1432816032; called by muse, varscan2
- DOLK | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 131/241 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs748688866, COSV58279938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FREM3 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 42/201 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1390482820; called by muse, mutect2, varscan2
- KIF7 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs768030553; called by muse, mutect2
- LYPD8 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 79/544 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs370124764; called by muse, mutect2, varscan2
- MAPK11 | c.448-6C>T | Splice Region (SNP) | VAF 71/321 reads (22%) | catalogued as rs985435138; called by muse, mutect2, varscan2
- MISP | c.1426A>G p.K476E | Missense Mutation (SNP) | VAF 47/223 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs190920819; called by muse, mutect2, varscan2
- NDRG4 | c.215G>T p.G72V (on ENST00000570248 / NM_001378344.1; = p.G104V on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50751235; called by muse, mutect2, varscan2
- OR10G7 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 71/414 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV57866725; called by muse, mutect2, varscan2
- OR1C1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV101376280, COSV68715856; called by muse, mutect2, varscan2
- OVCH1 | c.933G>T p.R311S | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs755776403; called by muse, mutect2, varscan2
- PCDHGA5 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 247/464 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.638); catalogued as rs773568307, COSV99534624; called by muse, mutect2, varscan2
- PKHD1L1 | c.10829G>T p.G3610V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1445313168; called by muse, mutect2
- PKN1 | c.1588G>C p.G530R | Missense Mutation (SNP) | VAF 61/330 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.35); catalogued as COSV54394951; called by muse, mutect2, varscan2
- SIRPA | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 104/325 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs573686249; called by muse, mutect2, varscan2
- SLC10A2 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 152/352 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs146712120; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SORCS3 | c.2758C>T p.R920* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | catalogued as rs879267207; called by muse, mutect2, varscan2
- SRRM2 | c.5231G>A p.R1744Q | Missense Mutation (SNP) | VAF 142/289 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs200616521, COSV57074161; called by muse, mutect2, varscan2
- STRN3 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766739305; called by muse, mutect2, varscan2
- TENM1 | c.2744G>A p.G915E | Missense Mutation (SNP) | VAF 87/524 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64444850; called by muse, mutect2, varscan2
- TLR9 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.3); catalogued as rs746908600, COSV62345572; called by muse, mutect2
- TMEM72 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs201585558; called by muse, mutect2
- UGT2B11 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV71423021; called by muse, varscan2
- UGT3A2 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.907); catalogued as rs745757904; called by muse, mutect2, varscan2
- USP5 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs782574953; called by muse, mutect2, varscan2
- ZNF613 | c.809G>A p.R270H (on ENST00000293471 / NM_001031721.4; = p.R234H on NM_024840.4) | Missense Mutation (SNP) | VAF 119/265 reads (45%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.498); catalogued as rs540973466, COSV53272333; called by muse, varscan2
- ZNF654 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs773897741, COSV58806530; called by muse, mutect2, varscan2
- ZSCAN18 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.052); catalogued as rs1254138367; called by muse, mutect2, varscan2
- ADAMTS13 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 130/509 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- APC | c.3910del p.I1304* | Frame Shift Del (DEL) | VAF 196/460 reads (43%) | called by mutect2, pindel, varscan2
- ASTN1 | c.3505A>T p.S1169C | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BAHD1 | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, varscan2
- BTBD7 | c.2638A>G p.T880A | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); called by muse, mutect2
- C4BPB | c.231C>A p.R77= | Splice Region (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- CCND1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 52/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CMTM6 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 100/310 reads (32%) | called by muse, mutect2, varscan2
- COL1A2 | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 116/700 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUBN | c.10481T>C p.V3494A | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYB5R1 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDA2R | c.880G>T p.V294F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- ELAPOR1 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 69/271 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ENPP2 | c.416A>T p.K139I | Missense Mutation (SNP) | VAF 97/247 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- ERCC8 | c.639del p.L213Ffs*4 | Frame Shift Del (DEL) | VAF 51/234 reads (22%) | called by mutect2, pindel, varscan2
- FGFR1 | c.890G>A p.G297E (on ENST00000447712 / NM_023110.3; = p.G295E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/364 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- FMNL3 | c.111G>T p.R37S | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- GPT | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 117/576 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRIN3B | c.1734G>C p.W578C | Missense Mutation (SNP) | VAF 129/529 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HNRNPM | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 129/517 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ICA1L | c.818A>T p.D273V | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- IGSF10 | c.3950C>A p.A1317E | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- INSRR | c.2738-1G>C p.X913_splice | Splice Site (SNP) | VAF 45/144 reads (31%) | called by muse, mutect2, varscan2
- INSRR | c.2738-2A>C p.X913_splice | Splice Site (SNP) | VAF 44/141 reads (31%) | called by muse, mutect2, varscan2
- KALRN | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KPRP | c.218A>C p.K73T | Missense Mutation (SNP) | VAF 141/362 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MADCAM1 | c.1114A>G p.R372G | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAGEL2 | c.3742C>A p.P1248T | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.903); called by muse, varscan2
- MAPK8IP2 | c.1852C>T p.R618W | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MC4R | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MOGS | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAP1L4 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- NCAN | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NID1 | c.372A>T p.E124D | Missense Mutation (SNP) | VAF 60/342 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- OR5H14 | c.142G>T p.V48F | Missense Mutation (SNP) | VAF 83/332 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PARVG | c.758G>A p.G253D | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PCDHB10 | c.1063T>A p.S355T | Missense Mutation (SNP) | VAF 54/491 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RASAL2 | c.483+1G>T p.X161_splice | Splice Site (SNP) | VAF 48/190 reads (25%) | called by muse, mutect2, varscan2
- RIF1 | c.5964_5965del p.E1989Dfs*3 | Frame Shift Del (DEL) | VAF 81/269 reads (30%) | called by mutect2, pindel, varscan2
- SHANK1 | c.4874C>A p.T1625K | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SMARCC1 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SMO | c.2198T>C p.V733A | Missense Mutation (SNP) | VAF 223/607 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SORCS2 | c.2339C>A p.P780H | Missense Mutation (SNP) | VAF 54/313 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRRAP | c.1211A>T p.K404M | Missense Mutation (SNP) | VAF 84/568 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TSBP1 | c.859dup p.M287Nfs*8 (on ENST00000617061; = p.M290Nfs*8 on NM_006781.5) | Frame Shift Ins (INS) | VAF 39/184 reads (21%) | called by mutect2, pindel, varscan2
- UNC79 | c.3420C>A p.D1140E (on ENST00000393151 / NM_001346218.2; = p.D963E on NM_020818.5) | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF227 | c.2386G>A p.G796S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ADAMTS10 | c.1014C>T p.N338= | Silent (SNP) | VAF 278/616 reads (45%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.2733C>A p.P911= | Silent (SNP) | VAF 48/185 reads (26%) | catalogued as rs749294596; called by muse, mutect2, varscan2
- ADGRV1 | c.2838T>C p.T946= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as rs1428739550; called by muse, mutect2, varscan2
- ASB18 | c.807C>T p.H269= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.3150C>T p.T1050= (on ENST00000479441 / NM_001174051.3; = p.T1043= on NM_006030.4) | Silent (SNP) | VAF 75/272 reads (28%) | catalogued as rs780332550; called by muse, mutect2, varscan2
- CENPF | c.6423A>G p.K2141= | Silent (SNP) | VAF 51/252 reads (20%) | called by muse, mutect2, varscan2
- COL1A2 | c.2322T>A p.A774= | Silent (SNP) | VAF 118/700 reads (17%) | called by muse, mutect2, varscan2
- COL6A1 | c.2853G>A p.T951= | Silent (SNP) | VAF 39/204 reads (19%) | catalogued as rs890068806; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CRCP | c.330G>A p.E110= | Silent (SNP) | VAF 47/267 reads (18%) | called by muse, mutect2, varscan2
- CYP4F8 | c.552G>A p.E184= | Silent (SNP) | VAF 47/221 reads (21%) | catalogued as rs374578505; called by muse, mutect2, varscan2
- DCHS2 | c.1215C>T p.D405= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as rs1220284219; called by muse, mutect2
- DOCK4 | c.4878A>C p.V1626= | Silent (SNP) | VAF 57/178 reads (32%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.7215G>A p.G2405= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs1567012071, COSV100794861; ClinVar: likely benign; called by muse, mutect2
- ECM1 | c.540C>T p.I180= | Silent (SNP) | VAF 98/573 reads (17%) | called by muse, mutect2, varscan2
- EDA2R | c.699C>T p.S233= | Silent (SNP) | VAF 58/150 reads (39%) | catalogued as COSV99490433; called by muse, mutect2, varscan2
- EME1 | c.354A>G p.P118= | Silent (SNP) | VAF 45/162 reads (28%) | called by muse, mutect2, varscan2
- FLG | c.6057C>T p.H2019= | Silent (SNP) | VAF 294/1498 reads (20%) | catalogued as rs758176214, COSV64240888; called by muse, mutect2
- FNIP1 | c.1989T>C p.V663= | Silent (SNP) | VAF 50/194 reads (26%) | catalogued as CD134243; called by muse, mutect2, varscan2
- FPR2 | c.339C>T p.V113= | Silent (SNP) | VAF 75/350 reads (21%) | called by muse, mutect2, varscan2
- GPR137 | c.537C>T p.S179= | Silent (SNP) | VAF 166/745 reads (22%) | catalogued as rs371290655; called by muse, mutect2, varscan2
- IGHA1 | c.552C>T p.S184= | Silent (SNP) | VAF 90/309 reads (29%) | catalogued as rs762122332; called by muse, mutect2, varscan2
- IRS1 | c.3132G>A p.P1044= | Silent (SNP) | VAF 75/173 reads (43%) | catalogued as rs773858412, COSV59340641; called by muse, mutect2, varscan2
- KCTD15 | c.792G>A p.E264= | Silent (SNP) | VAF 44/177 reads (25%) | called by muse, mutect2, varscan2
- LRRC37B | c.1998G>T p.L666= | Silent (SNP) | VAF 48/177 reads (27%) | called by muse, varscan2
- MUC4 | c.10209A>T p.T3403= | Silent (SNP) | VAF 118/796 reads (15%) | called by muse, varscan2
- NALCN | c.1263G>A p.A421= | Silent (SNP) | VAF 63/146 reads (43%) | catalogued as rs140469887; called by muse, mutect2, varscan2
- NLRP11 | c.2454C>T p.Y818= | Silent (SNP) | VAF 96/200 reads (48%) | catalogued as rs199475861; ClinVar: not provided; called by muse, mutect2, varscan2
- NLRP3 | c.2685G>A p.T895= | Silent (SNP) | VAF 186/564 reads (33%) | catalogued as rs778287953, COSV60223984; called by muse, mutect2, varscan2
- NRXN1 | c.465C>T p.V155= | Silent (SNP) | VAF 117/280 reads (42%) | catalogued as rs531571569, COSV68004656; called by muse, mutect2, varscan2
- OR10G7 | c.468T>A p.A156= | Silent (SNP) | VAF 72/421 reads (17%) | called by muse, mutect2, varscan2
- OR52L1 | c.954C>A p.R318= | Silent (SNP) | VAF 40/144 reads (28%) | called by muse, mutect2, varscan2
- OR5H14 | c.327C>A p.T109= | Silent (SNP) | VAF 55/227 reads (24%) | called by muse, mutect2, varscan2
- OR8B8 | c.105C>T p.Y35= | Silent (SNP) | VAF 122/296 reads (41%) | catalogued as rs140268238, COSV60144530; called by muse, mutect2, varscan2
- P2RX7 | c.1206C>A p.S402= | Silent (SNP) | VAF 39/131 reads (30%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4668C>T p.C1556= | Silent (SNP) | VAF 69/482 reads (14%) | called by muse, mutect2, varscan2
- PIK3C2B | c.3552C>T p.C1184= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV65811177; called by muse, mutect2, varscan2
- PRLH | c.186C>T p.D62= | Silent (SNP) | VAF 89/257 reads (35%) | called by muse, mutect2, varscan2
- PRND | c.321C>T p.G107= | Silent (SNP) | VAF 273/829 reads (33%) | called by muse, mutect2, varscan2
- PTPRR | c.462T>C p.N154= | Silent (SNP) | VAF 41/221 reads (19%) | called by muse, mutect2, varscan2
- SLC38A6 | c.1431C>T p.C477= | Silent (SNP) | VAF 40/158 reads (25%) | called by muse, mutect2
- SOX8 | c.453C>T p.F151= | Silent (SNP) | VAF 23/212 reads (11%) | catalogued as rs572388048; called by muse, mutect2
- SULT1C3 | c.696C>A p.I232= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs1558668606, COSV100227451; called by muse, mutect2, varscan2
- TAS1R3 | c.2130C>T p.D710= | Silent (SNP) | VAF 207/368 reads (56%) | called by muse, mutect2, varscan2
- TNRC18 | c.3063C>T p.Y1021= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs965026108; called by muse, mutect2
- TSHZ1 | c.723G>A p.T241= (on ENST00000580243 / NM_001308210.2; = p.T196= on NM_005786.6) | Silent (SNP) | VAF 74/129 reads (57%) | catalogued as rs777460466; called by muse, mutect2, varscan2
- VPS9D1 | c.849G>A p.P283= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs112830886; called by muse, mutect2, varscan2
- VSTM2L | c.189C>T p.S63= | Silent (SNP) | VAF 61/531 reads (11%) | catalogued as rs1314428733, COSV65096376; called by muse, mutect2, varscan2
- ZNF541 | c.1497C>T p.C499= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1244066791; called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793358 G>A | 3'Flank (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- AC134312.1 | n.385_387del | RNA (DEL) | VAF 30/152 reads (20%) | called by pindel, varscan2
- AC136604.1 | n.541G>T | RNA (SNP) | VAF 228/429 reads (53%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57610214 A>T | 5'Flank (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- ART3 | c.847+47G>C | Intron (SNP) | VAF 50/252 reads (20%) | called by muse, mutect2, varscan2
- C7orf66 | n.294C>A | RNA (SNP) | VAF 60/427 reads (14%) | called by muse, mutect2, varscan2
- CHCHD5 | c.-18G>T | 5'UTR (SNP) | VAF 36/282 reads (13%) | called by muse, mutect2, varscan2
- CLUHP11 | n.201G>T | RNA (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2
- CNNM3 | c.*357C>T | 3'UTR (SNP) | VAF 108/253 reads (43%) | called by muse, mutect2, varscan2
- DAPK1 | c.1626+16A>G | Intron (SNP) | VAF 77/276 reads (28%) | called by muse, mutect2, varscan2
- FKBP6 | c.-145C>T | 5'UTR (SNP) | VAF 58/418 reads (14%) | called by muse, mutect2, varscan2
- FOXO3B | chr17:18662780 del T | 3'Flank (DEL) | VAF 24/102 reads (24%) | called by mutect2, varscan2
- FRMPD2B | n.896C>T | RNA (SNP) | VAF 173/660 reads (26%) | catalogued as rs1182139298; called by muse, mutect2, varscan2
- GP6 | c.*166A>T | 3'UTR (SNP) | VAF 106/597 reads (18%) | called by muse, mutect2, varscan2
- KCNH2 | c.1128+1853G>A | Intron (SNP) | VAF 81/388 reads (21%) | called by muse, mutect2, varscan2
- KLF4 | c.1100-42G>A | Intron (SNP) | VAF 36/98 reads (37%) | catalogued as rs376228612; called by muse, mutect2, varscan2
- LINC02691 | n.1436G>A | RNA (SNP) | VAF 44/163 reads (27%) | catalogued as rs1385989822; called by muse, mutect2, varscan2
- LY9 | c.454+1809C>A | Intron (SNP) | VAF 42/263 reads (16%) | called by muse, mutect2, varscan2
- MEGF8 | c.2737-33G>A | Intron (SNP) | VAF 26/149 reads (17%) | called by muse, mutect2, varscan2
- MYO1F | c.232-35C>T | Intron (SNP) | VAF 68/325 reads (21%) | called by muse, mutect2, varscan2
- NOP56 | c.570-23G>A | Intron (SNP) | VAF 92/591 reads (16%) | called by muse, mutect2, varscan2
- SLC13A3 | c.-23C>T | 5'UTR (SNP) | VAF 26/279 reads (9%) | called by muse, mutect2
- SLC2A10 | c.-40C>G | 5'UTR (SNP) | VAF 103/860 reads (12%) | catalogued as COSV100826385; called by muse, mutect2, varscan2
- TBXAS1 | c.-79-107C>T | Intron (SNP) | VAF 59/289 reads (20%) | called by muse, varscan2
- TMEM183B | n.70C>T | RNA (SNP) | VAF 72/268 reads (27%) | catalogued as rs1438306303; called by muse, mutect2, varscan2
- TSPAN14 | c.133-9C>G | Intron (SNP) | VAF 98/442 reads (22%) | called by muse, mutect2, varscan2
- WSCD2 | c.1346-3437C>T | Intron (SNP) | VAF 113/297 reads (38%) | catalogued as rs920365329; called by muse, mutect2, varscan2
